Surgical pathology report (de-identified scan), TCGA case TCGA-06-0124, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0124-01A (Primary Tumor).

060 0124
[REDACTED]
PATH NO. [REDACTED]
[REDACTED]

PATHOLOGICAL DIAGNOSIS:

BRAIN, TEMPORAL, EXCISIONAL BIOPSY: GLIOBLASTOMA MULTIFORME.

Operation/Specimen: Brain, temporal lobe.

Clinical History and Pre-Op Dx: [REDACTED] with progressive left sided weakness, and headache. Has temporal lobe tumor extending to frontal lobe, with cystic area and irregular enhancement. Has past history of gastric carcinoma.

GROSS PATHOLOGY: Received fresh, one fragment, 1.5 x 1.2 x 0.9 cm. Soft reddish-brown, hemorrhagic. In total #1-3.

INTRAOPERATIVE CONSULTATION: Brain, temporal lobe: Astrocytoma, probably anaplastic.

SITE:right brain tumor. FIXATIVE: saline. TYPE:multiple irregularly-shaped portions of rubbery to firm, tan and pale red tissue. NUMBER OF PIECES:multiple. SIZE/VOL:50 x 50 x 20 mm. CASSETTES: 4, representative sections.
[REDACTED]

MICROSCOPIC: Portions of a cellular glial neoplastic proliferation with nuclear anaplasia, prominent fibrillary background, and occasional mitotic figures. Neoformed vessels are frequent, and there are extensive areas of necrosis.

ADDENDUM MICROSCOPIC: With immunostain for MIB-1, the proliferative index of the tumor cells is about 10%.
[REDACTED]
[REDACTED]
[REDACTED]

Source: NCI Genomic Data Commons file 468996e4-58e0-4088-8103-4f41a8bd85d4 (TCGA-06-0124.5BA4F4A0-E68C-4BAD-88BC-8DD9F399A653.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).